Somatic mutation profile of tumor specimen MMRF_1916_1_BM_CD138pos (aliquot MMRF_1916_1_BM_CD138pos_T1_KHS5U_L08110) from MMRF case MMRF_1916, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.2 years (27,463 days).
Specimen MMRF_1916_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6b2261a-8e9f-4439-83df-ba0d095f501e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1916_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1916_1_PB_WBC_C2_KHS5U_L08111; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16c22b40-589e-4b4c-94f5-606f879e606e

The open-access MAF lists 126 somatic variants for this specimen: 50 protein-altering or splice-affecting, 19 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 31, Silent 19, Intron 17, Nonsense Mutation 4, 5'Flank 3, RNA 3, Frame Shift Del 2, 5'UTR 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PYCR2 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758595075; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACE2 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53027598; called by muse, mutect2, varscan2
- FADS1 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.855); catalogued as rs755788898, COSV57245286; called by muse, mutect2
- FAT3 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53111526; called by muse, mutect2
- FAT4 | c.9593C>A p.S3198Y | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as COSV100628814; called by muse, mutect2, varscan2
- FOXL3 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1401332579; called by muse, mutect2, varscan2
- G6PC2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56371563; called by muse, mutect2, varscan2
- GRB10 | c.1265C>T p.T422M (on ENST00000398812; = p.T376M on NM_001001549.3) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs932870989, COSV60010417; called by muse, mutect2, varscan2
- HSF4 | c.361G>C p.V121L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs749388656; called by muse, mutect2, varscan2
- IGLV3-25 | c.45A>G p.T15= | Splice Region (SNP) | VAF 28/119 reads (24%) | catalogued as rs1362621361; called by muse, mutect2, varscan2
- IGLV4-60 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs375528362; called by muse, varscan2
- KAT14 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV66608062; called by muse, mutect2, varscan2
- MAST3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99446498; called by muse, mutect2, varscan2
- NKX6-2 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1461695402, COSV100888336; called by muse, mutect2, varscan2
- OSBP2 | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV60239072; called by muse, mutect2, varscan2
- PCDHA12 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.02); catalogued as rs782516629; called by muse, mutect2
- PTCHD3 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV71256278, COSV71256722; called by muse, mutect2, varscan2
- RIMS1 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1360506533; called by muse, mutect2, varscan2
- RPH3AL | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as rs370635814; called by muse, mutect2, varscan2
- RUBCNL | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as rs372724179; called by muse, mutect2, varscan2
- SLCO1B3 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV53935472; called by muse, mutect2
- SYT13 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV99074638; called by muse, varscan2
- CASKIN1 | c.3475G>A p.A1159T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCNL1 | c.534A>C p.K178N | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH7 | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CHODL | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, varscan2
- CLEC16A | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- COL6A3 | c.7453C>T p.Q2485* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- CPO | c.495G>A p.W165* | Nonsense Mutation (SNP) | VAF 40/233 reads (17%) | called by muse, mutect2, varscan2
- DIP2A | c.1841C>A p.S614Y | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FANCM | c.4294G>A p.G1432R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPATCH8 | c.1870del p.R624Vfs*19 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | called by mutect2, pindel, varscan2
- HOXB2 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLC2 | c.238A>C p.K80Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL22RA2 | c.119A>C p.N40T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2B | c.4115C>G p.S1372* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- LRRC8C | c.1511G>A p.R504K | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYO1F | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OBSCN | c.13147del p.S4383Rfs*30 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel, varscan2
- PCDHB1 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2
- PIGW | c.1154T>G p.L385R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RIC1 | c.1127T>G p.V376G | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SLC16A1 | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SRSF1 | c.464A>G p.D155G | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TGFBR2 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TMPRSS15 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFRSF10B | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TNR | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSPYL1 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ZNF160 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ADAM18 | c.1158A>G p.L386= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, varscan2
- ADGRF5 | c.261C>T p.L87= | Silent (SNP) | VAF 11/207 reads (5%) | called by muse, mutect2
- BATF2 | c.465A>G p.S155= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- BPIFB4 | c.495G>A p.A165= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs755057163; called by muse, mutect2, varscan2
- C10orf71 | c.171G>A p.P57= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs199866549; called by muse, mutect2, varscan2
- EFTUD2 | c.1437T>G p.T479= | Silent (SNP) | VAF 41/254 reads (16%) | called by muse, mutect2, varscan2
- FAT1 | c.5379G>A p.V1793= | Silent (SNP) | VAF 36/156 reads (23%) | called by muse, mutect2, varscan2
- FRAS1 | c.8493C>T p.F2831= | Silent (SNP) | VAF 70/325 reads (22%) | catalogued as rs774409872, COSV53627676; called by muse, mutect2, varscan2
- KRT82 | c.1518C>A p.G506= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99233916; called by muse, varscan2
- LTBP4 | c.474C>T p.H158= (on ENST00000308370 / NM_001042544.1; = p.H121= on NM_003573.2) | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as rs554794571; called by muse, mutect2, varscan2
- MAPRE3 | c.801C>T p.D267= | Silent (SNP) | VAF 61/252 reads (24%) | catalogued as rs758876106; called by muse, mutect2, varscan2
- ONECUT2 | c.1461C>T p.D487= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs765657446, COSV72153039; called by muse, mutect2, varscan2
- PAX5 | c.7T>C p.L3= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV63907399; called by muse, mutect2, varscan2
- PIK3C2G | c.846C>G p.L282= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99854469; called by muse, mutect2, varscan2
- S1PR3 | c.441C>T p.D147= | Silent (SNP) | VAF 48/253 reads (19%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1101C>T p.R367= | Silent (SNP) | VAF 38/153 reads (25%) | called by muse, mutect2, varscan2
- STX18 | c.39C>A p.V13= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- USP6 | c.441C>T p.D147= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs767616918, COSV51484773; called by muse, mutect2
- XIRP2 | c.15G>A p.Q5= | Silent (SNP) | VAF 72/295 reads (24%) | catalogued as COSV54709288; called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551326 T>C | 5'Flank (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- AP003062.1 | n.915A>G | RNA (SNP) | VAF 6/14 reads (43%) | catalogued as rs753927394; called by muse, mutect2
- ATP2A2 | c.*942G>A | 3'UTR (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- ATP6V1G2 | chr6:31546702 C>T | 5'Flank (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021460 G>A | 5'Flank (SNP) | VAF 14/76 reads (18%) | catalogued as rs1360224388, COSV55846390; called by muse, mutect2
- C2CD3 | c.-92G>A | 5'UTR (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.2721+786G>T | Intron (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- CCSER1 | c.2217+239302dup | Intron (INS) | VAF 40/186 reads (22%) | catalogued as rs745913204; called by mutect2, pindel, varscan2
- CCT5 | c.993+119G>A | Intron (SNP) | VAF 15/39 reads (38%) | catalogued as rs1277458445; called by muse, mutect2
- CDC42BPB | c.*1011C>A | 3'UTR (SNP) | VAF 36/118 reads (31%) | called by muse, mutect2, varscan2
- CHCHD1 | c.243+210T>C | Intron (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- CUX1 | c.141+16371G>C | Intron (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- DCLK1 | c.*3070A>C | 3'UTR (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- DDX42 | c.2112+113G>A | Intron (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2
- EFR3B | c.*65C>T | 3'UTR (SNP) | VAF 33/120 reads (28%) | catalogued as rs1184742663; called by muse, mutect2, varscan2
- EIF5AL1 | c.*313T>A | 3'UTR (SNP) | VAF 14/49 reads (29%) | catalogued as rs1183211744, COSV73123018; called by mutect2, varscan2
- ELMO1 | c.*510A>G | 3'UTR (SNP) | VAF 16/62 reads (26%) | called by muse, varscan2
- EXOSC6 | c.*289T>G | 3'UTR (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- FNDC3B | c.*1674T>G | 3'UTR (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- FSTL5 | c.*784A>C | 3'UTR (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- GTF2A2 | c.*699A>G | 3'UTR (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.*629T>C | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- HMGCL | c.*244G>T | 3'UTR (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- IGLJ6 | chr22:22919776 A>C | 3'Flank (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2
- KEL | c.1772-45C>A | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- LINC02448 | n.332T>G | RNA (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- LRRN3 | c.*375C>T | 3'UTR (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- LTB | c.208+53C>T | Intron (SNP) | VAF 53/153 reads (35%) | catalogued as rs573864094; called by muse, mutect2, varscan2
- MAP9 | c.*2637G>C | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- MGST3 | c.117+62G>A | Intron (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- MLF2 | c.-28-260T>C | Intron (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- MUS81 | c.*144C>T | 3'UTR (SNP) | VAF 11/63 reads (17%) | catalogued as rs944618018; called by muse, mutect2, varscan2
- NAP1L1 | c.430-536T>C | Intron (SNP) | VAF 40/150 reads (27%) | called by mutect2, varscan2
- NDUFA9 | c.*1644C>T | 3'UTR (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- NEK7 | c.58-7735A>G | Intron (SNP) | VAF 53/183 reads (29%) | catalogued as rs909016551; called by muse, mutect2, varscan2
- NFIA | c.*4843C>A | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- NR3C2 | c.*1834A>C | 3'UTR (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- PASK | c.*378A>C | 3'UTR (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- PCSK1 | c.*801A>G | 3'UTR (SNP) | VAF 11/71 reads (15%) | catalogued as rs969935780; called by muse, mutect2, varscan2
- PGM3 | c.*4195T>A | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- PHACTR2 | c.*5565T>C | 3'UTR (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- PIGQ | c.942+50C>T | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- POU2F2 | c.1198+50G>A | Intron (SNP) | VAF 56/151 reads (37%) | called by muse, mutect2, varscan2
- PRLR | c.*768T>C | 3'UTR (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- PRRC2A | c.6148-12T>C | Intron (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- PTCD3 | c.1238-74T>G | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- RGP1 | c.*1771G>A | 3'UTR (SNP) | VAF 30/129 reads (23%) | catalogued as rs1452037562; called by muse, mutect2, varscan2
- SPATA31C2 | n.443T>A | RNA (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- SPRR1B | c.*53T>C | 3'UTR (SNP) | VAF 301/669 reads (45%) | called by muse, mutect2, varscan2
- TAPT1 | c.*2625A>G | 3'UTR (SNP) | VAF 11/51 reads (22%) | catalogued as rs1364609968; called by muse, mutect2, varscan2
- TCP11L1 | c.*113G>A | 3'UTR (SNP) | VAF 11/55 reads (20%) | catalogued as rs895540283, COSV57517468; called by muse, mutect2, varscan2
- THAP9 | c.*407T>G | 3'UTR (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- TRPM3 | c.1154+8641G>T | Intron (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- UBA2 | c.-2C>T | 5'UTR (SNP) | VAF 8/46 reads (17%) | catalogued as rs1451989280; called by muse, mutect2
- UBE2H | c.*2111dup | 3'UTR (INS) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- VAPA | c.*684A>G | 3'UTR (SNP) | VAF 7/63 reads (11%) | catalogued as rs984870952; called by muse, mutect2, varscan2
- ZNF862 | c.*1580C>A | 3'UTR (SNP) | VAF 6/27 reads (22%) | called by muse, varscan2
